CCDI case PBCWGY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/edb3337a-e8cf-45c1-94c9-785c8ac02816

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Sample 0E1KO6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1KOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
